Somatic mutation profile of tumor specimen TCGA-XF-A9SU-01A (aliquot TCGA-XF-A9SU-01A-31D-A391-08) from TCGA case TCGA-XF-A9SU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,068 days).
Specimen TCGA-XF-A9SU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b06411c7-f092-4efe-ad68-e6859c11785e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SU-10A (Blood Derived Normal), aliquot TCGA-XF-A9SU-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6acd3a54-009a-44fd-9e50-0def655bd088

The open-access MAF lists 55 somatic variants for this specimen: 46 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 43, Silent 9, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/73 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV58159334; called by muse, mutect2, varscan2
- ATAD2 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV54883477; called by muse, mutect2, varscan2
- BAIAP2L1 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 58/229 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765327861, COSV50057558; called by muse, mutect2, varscan2
- C11orf71 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as rs371890478; called by muse, mutect2, varscan2
- CADM2 | c.242G>A p.R81H (on ENST00000407528 / NM_001167674.2; = p.R83H on NM_153184.4) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs778733322, CM145841, COSV67385719, COSV67414308; called by muse, mutect2, varscan2
- CCDC178 | c.127A>C p.M43L | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100285267; called by muse, mutect2
- COBL | c.3653C>G p.S1218C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99472943; called by muse, mutect2
- COL4A1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519191, COSV65428215; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSNK2A1 | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53936175; called by muse, mutect2, varscan2
- CTSL | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1326260085, COSV58246737; called by muse, mutect2, varscan2
- DNAH17 | c.9943G>A p.D3315N | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.42); PolyPhen probably damaging (1); catalogued as rs142069633; called by muse, mutect2, varscan2
- DSCAML1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV100356303; called by muse, mutect2
- DTWD2 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs1381051531, COSV100407012; called by muse, mutect2
- EFCAB6 | c.2373G>C p.L791F | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV53066987; called by muse, mutect2, varscan2
- FILIP1 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52734792; called by muse, mutect2, varscan2
- HERC1 | c.13027A>G p.K4343E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV71245858, COSV71248591; called by muse, mutect2
- ISYNA1 | c.1324T>C p.F442L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs750619194, COSV54210967; called by muse, mutect2, varscan2
- KCNK9 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV100271188; called by muse, mutect2
- KIF1A | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as rs759791775, COSV57494340; called by muse, mutect2, varscan2
- LDAH | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.047); catalogued as COSV52971722; called by muse, mutect2, varscan2
- LRRC31 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.111); catalogued as COSV52981676; called by muse, mutect2, varscan2
- MAGED2 | c.1271+1G>T p.X424_splice | Splice Site (SNP) | VAF 13/91 reads (14%) | catalogued as COSV54498665; called by muse, mutect2, varscan2
- MRPL1 | c.694A>C p.K232Q | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as COSV59675788; called by muse, mutect2, varscan2
- MSL2 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs751463655, COSV53867104; called by muse, mutect2, varscan2
- MYBBP1A | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs749510484, COSV54593739, COSV99626311; called by muse, mutect2
- PCDHB3 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV50565638; called by muse, mutect2, varscan2
- PCDHB7 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as rs782219988, COSV99177084; called by muse, mutect2
- PCSK2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV52737328; called by muse, mutect2, varscan2
- PLXNA2 | c.2662T>C p.S888P | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.658); catalogued as COSV65442446; called by muse, mutect2
- RIMS4 | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1568892913, COSV65720109; called by muse, mutect2, varscan2
- SACS | c.11818G>A p.V3940M | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV66543344; called by muse, mutect2, varscan2
- SSH1 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV58457956; called by muse, mutect2
- SYTL2 | c.1795C>T p.L599F (on ENST00000528231 / NM_001162951.2; = p.L1888F on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as COSV60360805; called by muse, mutect2
- TG | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99601491; called by muse, mutect2
- TNFSF13B | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs1435139414, COSV65516588; called by muse, mutect2, varscan2
- TRMU | c.478+2dup p.X160_splice | Splice Site (INS) | VAF 12/110 reads (11%) | catalogued as rs1370283982; called by mutect2, varscan2
- TTBK1 | c.2092C>T p.R698W | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs763736859, COSV52493698; called by muse, mutect2, varscan2
- TYR | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV54480158; called by muse, mutect2
- UBAP1 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV52660053; called by muse, mutect2, varscan2
- VCAN | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as rs377090663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WEE1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV55197353; called by muse, mutect2, varscan2
- ZMAT4 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV52705635; called by muse, mutect2, varscan2
- ZNF628 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.625); catalogued as rs747339144, COSV52700779; called by muse, mutect2, varscan2
- IGHG3 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ZFP36L1 | c.337_340dup p.R114Qfs*12 | Frame Shift Ins (INS) | VAF 25/180 reads (14%) | called by mutect2, pindel, varscan2
- ATP8B3 | c.3657C>T p.A1219= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV100034530; called by muse, mutect2
- FAR1 | c.1146T>C p.T382= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV61385497; called by muse, mutect2, varscan2
- FERMT1 | c.1335C>T p.A445= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs751428620, COSV54094905; called by muse, mutect2, varscan2
- HYAL4 | c.261C>T p.V87= | Silent (SNP) | VAF 4/77 reads (5%) | catalogued as COSV99772294; called by muse, mutect2
- INTS6L | c.63C>T p.G21= | Silent (SNP) | VAF 33/169 reads (20%) | catalogued as COSV66085077; called by muse, mutect2, varscan2
- IQSEC3 | c.2766A>G p.S922= (on ENST00000538872 / NM_001170738.2; = p.S619= on NM_015232.1) | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV58287192; called by muse, mutect2, varscan2
- PCDHA1 | c.2034G>A p.A678= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs562110007, COSV65375424; called by muse, mutect2
- PCDHA1 | c.2202G>A p.P734= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs374247491, COSV65372814; called by muse, mutect2
- ZFYVE26 | c.2428C>A p.R810= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV61330719; called by muse, mutect2, varscan2
